Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A71D, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A71D-01A (Primary Tumor).

ICD-0-3

Carcinoma, squamous
cell NOS 8670/3

Site Larynx NOS C32.9

8/9/13

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Larynx

- 1 - "Left neck dissection specimen levels 2, 3 and 4":
- Twelve lymph nodes with no evidence of metastatic carcinoma (0/12).
- 2 - "Right neck dissection specimen levels 2, 3 and 4":
- Thirty lymph nodes with no evidence of metastatic carcinoma (0/30).
- 3 - "Total laryngectomy and total thyroidectomy specimen":
- Larynx
- Moderately differentiated squamous cell carcinoma involving bilateral vocal cords, preepiglottic space, thyroid cartilage and perithyroidal soft tissue
- Tumor size: 3.5 cm
- Lymphovascular invasion: absent
- Perineural invasion: absent
- Margins uninvolved by invasive tumor.

Thyroid:

Papillary microcarcinoma (3 focuses; the major focus measures 0.4 cm)
Absence of vascular invasion and extrathyroidal invasion.
Adenomatous goiter with hyperplastic nodule.

Qual Synchronous Primary Noted	NO rx	✓

Source: NCI Genomic Data Commons file 860278d4-7b17-4624-949b-16583998ff85 (TCGA-UF-A71D.851F570C-85A6-423D-9204-45C81772424E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).